Somatic mutation profile of tumor specimen TARGET-15-SJMPAL043514-09A (aliquot TARGET-15-SJMPAL043514-09A-01D) from TARGET case TARGET-15-SJMPAL043514, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,752 days).
Specimen TARGET-15-SJMPAL043514-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d871657-8159-4e0e-aa1d-76a3a256b6f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL043514-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL043514-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b3822c7-963f-4a8a-a855-372f0376ddbd

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 1, Nonsense Mutation 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 149/394 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs148654695, COSV51804455; called by muse, mutect2, varscan2
- NTRK1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs141483265; called by muse, mutect2
- OLFM2 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 182/376 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233551999; called by muse, mutect2, varscan2
- PLXDC2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 190/429 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745577270, COSV65924513; called by muse, mutect2, varscan2
- PRKD2 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs902275668; called by muse, mutect2, varscan2
- PXDNL | c.1976C>A p.A659E | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62477066; called by muse, mutect2, varscan2
- DCAF12L2 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAS2L1 | c.1008C>A p.P336= | Splice Region (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- NPW | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- OLFM2 | c.1252T>A p.S418T | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIAS3 | c.1640T>A p.I547N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLITRK2 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLX3 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- ZFP69B | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2
- DGKA | c.729C>T p.H243= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs767547527; called by muse, mutect2, varscan2
- F3 | c.279C>T p.D93= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs775151591; called by muse, mutect2, varscan2
- FUZ | c.648C>T p.T216= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs775009592; called by muse, mutect2, varscan2
- PHIP | c.1854C>T p.I618= | Silent (SNP) | VAF 102/257 reads (40%) | called by muse, mutect2, varscan2
- ACOT9 | c.-33G>T | 5'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SPATA5L1 | c.1275+1575G>A | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
